HCMI case HCM-WCMC-1287-C67 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Bladder. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/150dfaa3-1eb3-427a-a82f-560d706cabc2

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1946; Vital status: Dead; Days to death: 463 days (1.3 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Combined small cell carcinoma: ICD-O-3 morphology code: 8045/3; ICD-10 code: C67.9; Tissue or organ of origin: Bladder, NOS; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 74.8 years (27,327 days); Tumor grade: G3; Prior malignancy: yes; Prior treatment: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Etoposide; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 43 days; Days to treatment end: 155 days.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Avelumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 190 days; Days to treatment end: 260 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lurbinectedin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 365 days (1.0 years); Days to treatment end: 407 days (1.1 years).
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Enfortumab Vedotin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 435 days (1.2 years); Days to treatment end: 442 days (1.2 years).
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Hormone Therapy, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (2 entries)
- Days to follow up: 463 days (1.3 years); Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 316.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 77.1 kg; Height: 170.2 cm; BMI: 27.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Alcohol drinks per day: 1; Alcohol days per week: 6.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-WCMC-1287-C67-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide HCM-WCMC-1287-C67-01A-01-TS1-HE: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 2.
  Slide HCM-WCMC-1287-C67-01A-01-BS1-HE: Section location: Bottom; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 2.
- Sample HCM-WCMC-1287-C67-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-WCMC-1287-C67-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
